RC case RC-B555 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43078930-b7a7-4dcf-b0aa-aeab6d1880f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1964; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Mature T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,790 days); Year of diagnosis: 2018; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Weight Loss / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Lymph Node, Cervical / Bone, NOS / Soft tissue / Other.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 3 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOPE; Days to treatment start: 17 days; Days to treatment end: 17 days; Number of cycles: 1; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 18 days; Days to treatment end: 175 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHP; Days to treatment start: 50 days; Days to treatment end: 109 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 50 days; Days to treatment end: 109 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 156 days; Days to treatment end: 175 days; Treatment dose: 3,600 cGy; Treatment outcome: Complete Response; Number of fractions: 20; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 757 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Day 1,520 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2; Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day 1,583.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 215 U/L [Blood test normal range upper: 192].

Other clinical attributes
- Timepoint category: Follow-up; Comorbidities: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 108.8 kg; Height: 165.1 cm; BMI: 39.9.
- Timepoint category: Prior to Diagnosis; Comorbidities: Asthma / GERD / Migraine / Hypothyroidism.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 8; Tobacco smoking onset year: 2008.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Thyroid Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B555-NM1-A: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B555-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B555-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
